Gene-level copy-number profile of tumor specimen ALCH-B4VK-TTP1-A from ALCHEMIST case ALCH-B4VK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,579 days).
Specimen ALCH-B4VK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2d7b8dcb-d2d9-4bee-8165-e1ab411b3100.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4VK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/1f745852-e362-4ed3-af19-f6c753fc4d92

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 1,845; copy number 2: 44,866; copy number 3: 8,850; copy number 4: 2,691; copy number 5: 42; copy number 6: 6; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:916,865–921,016, 1 gene: LINC02593.
- chr1:12,838,125–12,928,253, 8 genes (within-gene range 0–5): PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P.
- chr1:27,098,809–27,166,981, 1 gene: SLC9A1.
- chr1:39,659,121–39,672,038, 1 gene: NT5C1A.
- chr4:68,509,441–68,517,647, 1 gene: UGT2B29P.
- chr7:128,830,406–128,862,626, 2 genes (within-gene range 0–1): FLNC, FLNC-AS1.
- chr8:143,790,920–143,815,773, 2 genes (within-gene range 0–4): SCRIB, MIR937.
- chr8:143,857,324–143,878,467, 1 gene: EPPK1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes (within-gene range 0–1): ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6.
- chr10:43,077,064–43,130,351, 1 gene: RET.
- chr10:80,131,682–80,145,359, 1 gene: PLAC9.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr14:104,724,229–104,747,325, 1 gene: ADSS1.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,825,099–41,848,155, 4 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–2): RNA5SP393.
- chr15:85,744,109–85,756,237, 3 genes (within-gene range 0–3): AC021739.2, AC021739.4, LINC02883.
- chr15:85,770,496–85,771,163, 2 genes (within-gene range 0–2): MIR1276, AC021739.1.
- chr16:707,650–711,277, 2 genes (within-gene range 0–3): Z97653.2, Z97653.1.
- chr16:10,718,633–10,719,762, 1 gene: MTCYBP33.
- chr16:32,600,299–32,615,639, 1 gene: AC137800.1.
- chr19:1,748,056–1,780,988, 2 genes: AC005256.1, ONECUT3.
- chr22:24,181,487–24,189,106, 1 gene: SUSD2.
- chr22:41,922,032–41,958,933, 4 genes: TNFRSF13C, MIR378I, CENPM, LINC00634.
- chr22:50,309,030–50,327,012, 3 genes: DENND6B, CR559946.1, CR559946.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,343,144, 2 genes, copy number 7: CR383658.1, RNU6-458P.
- chr14:105,546,610–105,601,728, 3 genes, copy number 5 (within-gene range 1–5): ELK2BP, IGHA2, IGHE.
- chr21:43,092,956–43,172,805, 6 genes, copy number 6: U2AF1, AP001631.2, MRPL51P2, FRGCA, AP001631.1, CRYAA.

Autosomal genes at a single copy (total copy number 1): 1,845. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
